Somatic mutation profile of tumor specimen TCGA-BR-8077-01A (aliquot TCGA-BR-8077-01A-11D-2340-08) from TCGA case TCGA-BR-8077, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.6 years (21,413 days).
Specimen TCGA-BR-8077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c39f309f-ce51-4894-886d-d5e17b4d1238.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8077-10A (Blood Derived Normal), aliquot TCGA-BR-8077-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20cea5e3-7277-4491-9e47-60c9d1f44e2e

The open-access MAF lists 120 somatic variants for this specimen: 94 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 22, Splice Region 3, Frame Shift Ins 2, RNA 2, Nonsense Mutation 1, 3'UTR 1, Splice Site 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH2 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs794728373, COSV51205142; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 23/34 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3605T>G p.V1202G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99228610; called by muse, varscan2
- ABCC6 | c.3604G>C p.V1202L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52741785, COSV99228613; called by muse, varscan2
- ACIN1 | c.2956A>C p.K986Q | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV52978270; called by muse, mutect2, varscan2
- ADGRE5 | c.1935C>G p.F645L (on ENST00000242786 / NM_078481.4; = p.F552L on NM_001784.5) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.963); catalogued as COSV54392287; called by muse, mutect2, varscan2
- ADGRV1 | c.10169G>A p.R3390K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV67989456; called by muse, mutect2, varscan2
- AIFM2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs749562741, COSV57159807; called by muse, mutect2, varscan2
- ATP1B1 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV63168467; called by muse, mutect2, varscan2
- CA3 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV53410408; called by muse, mutect2, varscan2
- CASP4 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs745951817, COSV67744590; called by muse, mutect2, varscan2
- CDH9 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV50328845, COSV99155952; called by muse, mutect2
- CDX4 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs777946946, COSV65171738; called by muse, mutect2, varscan2
- CDYL | c.1259G>T p.S420I (on ENST00000328908 / NM_001368125.1; = p.S366I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59360523; called by muse, mutect2, varscan2
- CEMIP | c.3281C>T p.S1094L | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.912); catalogued as rs750169411, COSV54992014, COSV54999840, COSV99586555; called by muse, mutect2, varscan2
- CLCN1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368280521, CX942107; called by muse, mutect2, varscan2
- CNOT2 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV57504398; called by muse, mutect2
- CSF2RB | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs146404001, COSV53257443; called by muse, mutect2, varscan2
- CYP2F1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs763777278, COSV58528117; called by muse, mutect2, varscan2
- CYSLTR1 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64820607; called by muse, mutect2
- DAB2IP | c.1285G>T p.V429L (on ENST00000408936; = p.V401L on NM_032552.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99405243; called by muse, mutect2, varscan2
- DCAF12L2 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.86); PolyPhen benign (0.086); catalogued as COSV100758539, COSV63582082; called by muse, mutect2, varscan2
- DIDO1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV56622066; called by muse, mutect2, varscan2
- DLC1 | c.2144A>G p.E715G (on ENST00000276297 / NM_001348081.2; = p.E278G on NM_006094.5) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV52313331; called by muse, mutect2, varscan2
- DNAH7 | c.7037G>C p.G2346A | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56773225; called by muse, mutect2
- DNAJC17 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV55025615; called by muse, mutect2
- DUS4L-BCAP29 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.299); catalogued as rs200901846, COSV55930465; called by muse, mutect2, varscan2
- FBLN5 | c.1180A>G p.M394V | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as COSV50905390; called by muse, mutect2, varscan2
- FER | c.137T>A p.L46* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV55296484; called by muse, mutect2, varscan2
- GCK | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV61754723; called by muse, mutect2
- GLYAT | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as rs201464772, COSV53538774; called by muse, mutect2, varscan2
- GMPS | c.1644G>C p.R548S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV55810462; called by muse, mutect2, varscan2
- GPR32 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54514982; called by muse, mutect2, varscan2
- GPT | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV52953813; called by muse, mutect2, varscan2
- GTF2B | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV65137326; called by muse, mutect2, varscan2
- HAUS4 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52827713; called by muse, mutect2, varscan2
- HTR2C | c.1184T>A p.V395D | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV52217517; called by muse, mutect2, varscan2
- IGF2BP1 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV51733280; called by muse, mutect2
- INMT | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.385); catalogued as rs753027832, COSV50001345; called by muse, mutect2, varscan2
- IQGAP1 | c.4648G>A p.E1550K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV51587791; called by muse, mutect2
- KCNE3 | c.167A>T p.N56I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59552195; called by muse, mutect2, varscan2
- KNL1 | c.6501C>A p.F2167L (on ENST00000346991 / NM_170589.5; = p.F2141L on NM_144508.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100706335, COSV100706713; called by muse, mutect2
- KRTAP9-9 | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 48/1093 reads (4%) | SIFT deleterious (0.04); catalogued as COSV67454086; called by muse, mutect2
- LRP2 | c.5731A>G p.K1911E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.248); catalogued as COSV55561173; called by muse, mutect2, varscan2
- MACF1 | c.3029T>G p.F1010C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV58384306; called by muse, mutect2, varscan2
- MAGEA10 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54884766; called by muse, mutect2, varscan2
- MAP7D3 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.23); catalogued as rs762497051, COSV60171170, COSV60171596; called by muse, mutect2, varscan2
- MARK2 | c.522A>C p.R174S | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59285675; called by muse, mutect2, varscan2
- MKRN3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs140349866; called by muse, mutect2, varscan2
- MKRN3 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs373441581; called by muse, mutect2, varscan2
- MOSPD1 | c.479T>C p.L160S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV66189446; called by muse, mutect2, varscan2
- MRPL15 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV52638011; called by muse, mutect2, varscan2
- MSLNL | c.1644C>T p.S548= | Splice Region (SNP) | VAF 6/17 reads (35%) | catalogued as COSV53503808; called by muse, mutect2, varscan2
- MYBPC1 | c.62-2A>C p.X21_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV62254622; called by muse, mutect2
- MYO1B | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100268996; called by muse, mutect2, varscan2
- NAP1L2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs1304106096, COSV65172702; called by muse, mutect2, varscan2
- NCAM2 | c.132G>T p.A44= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as COSV53086652, COSV53101523; called by muse, varscan2
- NCOA7 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV57655154; called by muse, mutect2, varscan2
- NEB | c.9430G>C p.D3144H | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51432081; called by muse, mutect2, varscan2
- OR6C75 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.803); catalogued as COSV58552441; called by muse, mutect2, varscan2
- PC | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs780682688, COSV63081452; called by muse, mutect2, varscan2
- PCDHA11 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.104); catalogued as rs376620715, COSV56521586; called by muse, mutect2, varscan2
- PEG3 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.417); catalogued as rs1482965198, COSV55639022; called by muse, mutect2, varscan2
- PHRF1 | c.1080A>T p.K360N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as COSV52758464; called by muse, mutect2, varscan2
- PI4K2B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746603449, COSV53510576; called by muse, mutect2, varscan2
- POGZ | c.158T>A p.V53E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV55038414; called by muse, mutect2
- PON2 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56002572; called by muse, mutect2
- RETSAT | c.1528G>T p.G510W | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55527057; called by muse, mutect2, varscan2
- RNFT1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs764930051, COSV59870063; called by muse, mutect2, varscan2
- S100A7L2 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1209137965, COSV64194949, COSV64195328; called by muse, mutect2, varscan2
- S100PBP | c.1110G>A p.T370= | Splice Region (SNP) | VAF 8/38 reads (21%) | catalogued as rs773043117, COSV65110851; called by muse, mutect2
- SETX | c.4326T>G p.C1442W | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99809500; called by muse, mutect2
- SETX | c.4325G>A p.C1442Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs1456152621, COSV99809505; called by muse, mutect2
- SGPP1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55975813; called by muse, mutect2, varscan2
- SIRPD | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs946828638, COSV67546906; called by muse, mutect2
- SLC26A9 | c.293T>A p.L98H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61604084; called by muse, mutect2
- SPATA31A1 | c.3574dup p.T1192Nfs*14 | Frame Shift Ins (INS) | VAF 46/189 reads (24%) | catalogued as rs1405569820; called by mutect2, pindel, varscan2
- SPEF2 | c.5195G>A p.S1732N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV57430376; called by muse, mutect2, varscan2
- ST8SIA2 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 32/228 reads (14%) | PolyPhen probably damaging (0.99); catalogued as COSV51570881; called by muse, mutect2, varscan2
- TALDO1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs764703431, COSV59797910; called by mutect2, varscan2
- TMPRSS13 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV70626791; called by muse, mutect2, varscan2
- TNNT1 | c.790T>G p.F264V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.942); catalogued as COSV52572417; called by muse, mutect2, varscan2
- TRDMT1 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as COSV58320030; called by muse, mutect2
- TUSC3 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV65883969, COSV65884489; called by muse, mutect2, varscan2
- UNC5D | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54810074, COSV54813414; called by muse, mutect2, varscan2
- VN1R2 | c.1135A>C p.S379R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.233); catalogued as COSV100447869, COSV59038887; called by muse, mutect2, varscan2
- ZFPM2 | c.2819A>G p.Q940R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.157); catalogued as COSV65874615; called by muse, mutect2, varscan2
- ZNF366 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); catalogued as COSV59216985; called by muse, mutect2, varscan2
- ZNF572 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1476094092, COSV60002219; called by muse, mutect2
- MYH10 | c.3950_3952dup p.L1317dup | In Frame Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2
- PRAMEF19 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 37/572 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.105); called by muse, mutect2
- SRBD1 | c.2575dup p.I859Nfs*6 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- TRBV6-1 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ABCC6 | c.3603C>T p.L1201= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs756077096, COSV52745384, COSV99228615; called by muse, varscan2
- ADSL | c.540C>T p.C180= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV53408621; called by muse, mutect2, varscan2
- AKAP6 | c.3747G>A p.L1249= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV55220786; called by muse, mutect2, varscan2
- APOA2 | c.243G>A p.T81= | Silent (SNP) | VAF 72/167 reads (43%) | catalogued as rs138452270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AR | c.897A>T p.A299= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV65959550; called by muse, mutect2, varscan2
- CCNYL1 | c.645C>T p.Y215= (on ENST00000295414 / NM_001330218.2; = p.Y145= on NM_152523.2) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs771312971, COSV54941041; called by muse, mutect2
- CDC20B | c.1413G>T p.V471= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV57054221; called by muse, mutect2, varscan2
- COL4A6 | c.3660G>T p.G1220= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as COSV57871161; called by muse, varscan2
- EBF3 | c.966C>T p.G322= (on ENST00000355311 / NM_001375392.1; = p.G313= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs151206880; called by muse, mutect2, varscan2
- FAM53A | c.468C>T p.G156= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1224333518, COSV57402242; called by muse, mutect2
- GALNT11 | c.870C>T p.V290= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV57426990; called by muse, mutect2
- GJD2 | c.207C>T p.R69= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs199516045; called by muse, mutect2, varscan2
- KLHL36 | c.1230G>A p.A410= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs777956919, COSV50718046; called by muse, mutect2, varscan2
- PLXNB2 | c.4623C>T p.R1541= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs369673593; called by muse, mutect2, varscan2
- RBBP6 | c.3579G>A p.R1193= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV60506511; called by muse, mutect2, varscan2
- SIAH3 | c.456G>A p.A152= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as rs1276477849, COSV68552383; called by muse, mutect2, varscan2
- SLC10A3 | c.840C>T p.D280= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs151043660, COSV54836534, COSV54836737; called by muse, mutect2, varscan2
- SLC30A10 | c.903G>A p.E301= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100751480; called by muse, mutect2
- SYNE2 | c.16281A>C p.P5427= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV59957259; called by muse, mutect2, varscan2
- TMEM45B | c.411C>T p.H137= | Silent (SNP) | VAF 38/181 reads (21%) | catalogued as rs934934425, COSV55654432; called by muse, mutect2, varscan2
- UGT3A2 | c.1197C>T p.V399= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as COSV56931780; called by muse, mutect2
- USP11 | c.126G>A p.T42= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs1256287962, COSV52092825; called by muse, mutect2, varscan2
- MIR323B | n.35G>A | RNA (SNP) | VAF 4/30 reads (13%) | catalogued as rs376647957; called by muse, mutect2
- PSG5 | c.431-2756T>G | Intron (SNP) | VAF 17/450 reads (4%) | catalogued as COSV100742733; called by muse, mutect2
- SCGB1D1 | c.*2A>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100086685; called by muse, mutect2, varscan2
- SNORD115-6 | n.53del | RNA (DEL) | VAF 33/316 reads (10%) | called by mutect2, pindel, varscan2
